EXCEPTIONAL_RESPONDERS case ER-B0AP — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/49651efc-0280-46ff-a3a3-d99ae861ae5c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1936; Vital status: Alive.

Diagnoses (1)
1. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,712 days); Year of diagnosis: 2007; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 3,732 days (10.2 years); Days to best overall response: 2,048 days (5.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Sunitinib Malate; Days to treatment start: 1,387 days (3.8 years).

Follow-up (1 entry)
- Days to follow up: 3,732 days (10.2 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,367 days (3.7 years); Days progression-free: 3,732 days (10.2 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0AP-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0AP-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0AP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-B0AP-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
